Somatic mutation profile of tumor specimen TCGA-ER-A2NB-01A (aliquot TCGA-ER-A2NB-01A-12D-A196-08) from TCGA case TCGA-ER-A2NB, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 57.7 years (21,062 days).
Specimen TCGA-ER-A2NB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8628980b-73e2-4de1-9574-5f87809fe24d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ER-A2NB-10A (Blood Derived Normal), aliquot TCGA-ER-A2NB-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/14e80aeb-e847-4dd9-9362-f63fdb49be0f

The open-access MAF lists 66 somatic variants for this specimen: 53 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 12, Frame Shift Del 2, Nonsense Mutation 2, Frame Shift Ins 1, Intron 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- B2M | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.192); catalogued as rs1023835002, COSV62562840, COSV62562870, COSV62563658; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 78/175 reads (45%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.800A>G p.Y267C | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.143); catalogued as rs1482816185, COSV58442628; called by muse, mutect2, varscan2
- ADGRL3 | c.2911C>T p.R971W (on ENST00000506720 / NM_001322402.2; = p.R903W on NM_015236.6) | Missense Mutation (SNP) | VAF 64/247 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747197228, COSV72230097; called by muse, mutect2, varscan2
- APOLD1 | c.730C>G p.L244V (on ENST00000326765 / NM_001130415.2; = p.L213V on NM_030817.3) | Missense Mutation (SNP) | VAF 4/98 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV58732408; called by muse, mutect2
- ASCC2 | c.961G>T p.E321* | Nonsense Mutation (SNP) | VAF 8/43 reads (19%) | catalogued as COSV100316322; called by muse, mutect2, varscan2
- ATP11C | c.2110A>G p.T704A | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV59561319; called by muse, mutect2
- ATP1A3 | c.1433A>G p.K478R (on ENST00000545399 / NM_001256214.2; = p.K465R on NM_152296.5) | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV57486491; called by muse, mutect2, varscan2
- BRINP3 | c.1571G>T p.W524L | Missense Mutation (SNP) | VAF 41/153 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV66518558; called by muse, mutect2, varscan2
- CMSS1 | c.604G>C p.E202Q | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.194); catalogued as COSV70436277; called by muse, mutect2, varscan2
- CTAGE1 | c.1591C>G p.P531A | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV66943204; called by muse, mutect2
- DSP | c.4672C>T p.R1558W | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as rs777102300, COSV65791236; called by muse, mutect2, varscan2
- ERAS | c.142G>A p.G48S | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV54432656; called by muse, mutect2
- GDNF | c.335G>A p.R112K | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV58478928; called by muse, mutect2, varscan2
- GRIA1 | c.782C>G p.T261S | Missense Mutation (SNP) | VAF 43/180 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV53596791, COSV53616202; called by muse, mutect2, varscan2
- GRIN2A | c.3808G>C p.D1270H | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.309); catalogued as COSV58027350; called by muse, mutect2, varscan2
- HOXA2 | c.1114C>T p.Q372* | Nonsense Mutation (SNP) | VAF 12/188 reads (6%) | catalogued as COSV56065726; called by muse, mutect2
- IARS2 | c.2494C>T p.R832C | Missense Mutation (SNP) | VAF 59/172 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56957822; called by muse, mutect2, varscan2
- KCNG1 | c.1285G>A p.D429N | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65368659; called by muse, mutect2, varscan2
- MAGEC1 | c.910C>A p.Q304K | Missense Mutation (SNP) | VAF 19/168 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.053); catalogued as COSV53570426; called by muse, mutect2, varscan2
- MED20 | c.584A>T p.E195V | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV54824773; called by muse, mutect2, varscan2
- MYH8 | c.2977G>A p.A993T | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV101238120, COSV67962510; called by muse, mutect2
- NEUROD6 | c.16T>G p.F6V | Missense Mutation (SNP) | VAF 10/316 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV51770862; called by muse, mutect2
- OR10S1 | c.787C>T p.L263F | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as COSV73342718; called by muse, mutect2, varscan2
- PDE6C | c.559G>A p.G187S | Missense Mutation (SNP) | VAF 9/119 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.658); catalogued as rs369094542; called by muse, mutect2
- PDLIM5 | c.565C>G p.Q189E | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.038); catalogued as COSV58746480; called by muse, mutect2
- PHC2 | c.892A>C p.S298R | Missense Mutation (SNP) | VAF 15/164 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.02); catalogued as rs750884230, COSV57103115; called by muse, mutect2
- PLD1 | c.29A>G p.N10S | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.006); catalogued as COSV60566662; called by muse, mutect2, varscan2
- PRPF40A | c.1756A>T p.T586S | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV62957167; called by muse, mutect2, varscan2
- PRUNE2 | c.5353G>C p.E1785Q | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as COSV65039845; called by muse, mutect2
- PTCHD1 | c.728C>G p.S243C | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.886); catalogued as COSV65059586, COSV65060169; called by muse, mutect2
- SEC14L1 | c.2077G>A p.G693S | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.545); catalogued as rs1417680404, COSV66721520; called by muse, mutect2, varscan2
- SERPINA7 | c.1108G>T p.V370F | Missense Mutation (SNP) | VAF 23/194 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as COSV59665342; called by muse, mutect2, varscan2
- SH3RF2 | c.266G>A p.R89H | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs775449544, COSV63038175; called by muse, mutect2, varscan2
- SLC8A1 | c.2522T>C p.V841A | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60475719; called by muse, mutect2
- SMG6 | c.1486G>A p.A496T | Missense Mutation (SNP) | VAF 57/277 reads (21%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV53965264, COSV99557916; called by muse, mutect2, varscan2
- TANC2 | c.508C>T p.P170S | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV67332592; called by muse, mutect2, varscan2
- TCP11 | c.37C>A p.P13T | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.058); catalogued as rs1381928600, COSV55132891; called by muse, mutect2, varscan2
- TFEC | c.46C>A p.Q16K | Missense Mutation (SNP) | VAF 65/131 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as COSV55399204; called by muse, mutect2, varscan2
- TMEM8B | c.1346G>C p.C449S | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV65076005; called by muse, mutect2
- TRIM27 | c.1519C>G p.H507D | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.599); catalogued as COSV65873401; called by muse, mutect2
- TRPV5 | c.241A>G p.T81A | Missense Mutation (SNP) | VAF 5/104 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as rs1354973615, COSV54684323; called by muse, mutect2
- TTN | c.6214A>C p.S2072R (on ENST00000591111; = p.S2026R on NM_003319.4) | Missense Mutation (SNP) | VAF 11/108 reads (10%) | PolyPhen probably damaging (0.962); catalogued as COSV59966306; called by muse, mutect2
- UBE3B | c.1897G>A p.D633N | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.048); catalogued as rs1344957917, COSV55092284; called by muse, mutect2
- UGT3A1 | c.1405A>G p.T469A | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57097026; called by muse, mutect2, varscan2
- UMOD | c.1660C>T p.R554W | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs752594445, COSV56774681; called by muse, mutect2, varscan2
- UPK2 | c.71C>A p.A24D | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.409); catalogued as rs751415447, COSV50628849; called by muse, mutect2, varscan2
- XKR3 | c.1249C>G p.P417A | Missense Mutation (SNP) | VAF 38/64 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.081); catalogued as COSV58885878; called by muse, varscan2
- ZNF367 | c.982C>T p.R328W | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs758616736, COSV53562291; called by muse, mutect2, varscan2
- ZNF804A | c.1779T>G p.S593R | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as rs1466271281; called by muse, varscan2
- ADAM15 | c.1352dup p.L451Ffs*14 | Frame Shift Ins (INS) | VAF 72/246 reads (29%) | called by mutect2, pindel, varscan2
- BRINP2 | c.1354del p.C452Afs*63 | Frame Shift Del (DEL) | VAF 16/54 reads (30%) | called by mutect2, varscan2
- ZNF804A | c.1773del p.H591Qfs*54 | Frame Shift Del (DEL) | VAF 14/94 reads (15%) | called by pindel, varscan2
- ATRNL1 | c.2607C>T p.G869= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as rs781800671, COSV58081115; called by muse, mutect2, varscan2
- CDC42BPB | c.4797C>T p.D1599= | Silent (SNP) | VAF 39/128 reads (30%) | catalogued as rs150855245; called by muse, mutect2, varscan2
- LAMA1 | c.8964T>G p.R2988= | Silent (SNP) | VAF 20/145 reads (14%) | catalogued as COSV101057618, COSV67534472; called by muse, mutect2, varscan2
- NTMT1 | c.78G>A p.T26= | Silent (SNP) | VAF 13/105 reads (12%) | catalogued as rs374990094; called by muse, mutect2, varscan2
- OR2Z1 | c.615G>T p.L205= | Silent (SNP) | VAF 7/105 reads (7%) | catalogued as COSV60692068; called by muse, mutect2
- OR4K17 | c.441C>A p.T147= | Silent (SNP) | VAF 21/74 reads (28%) | catalogued as COSV59647520; called by muse, mutect2, varscan2
- PKHD1L1 | c.8001C>T p.A2667= | Silent (SNP) | VAF 11/91 reads (12%) | catalogued as COSV101005527, COSV65740368; called by muse, mutect2, varscan2
- PNMA8A | c.156G>A p.P52= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as rs1439357969, COSV58136374; called by muse, mutect2, varscan2
- SLC26A8 | c.2862C>A p.R954= | Silent (SNP) | VAF 27/171 reads (16%) | catalogued as COSV62885285; called by muse, mutect2, varscan2
- STEAP3 | c.1341C>T p.A447= | Silent (SNP) | VAF 10/118 reads (8%) | catalogued as rs750824808, COSV61528461; called by muse, mutect2
- TNRC6B | c.4338T>C p.G1446= (on ENST00000454349 / NM_001162501.2; = p.G1336= on NM_015088.3) | Silent (SNP) | VAF 5/49 reads (10%) | catalogued as COSV57292333; called by muse, mutect2
- VRTN | c.366C>T p.G122= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV56439905; called by muse, mutect2
- TTN | c.10360+1200A>G | Intron (SNP) | VAF 70/198 reads (35%) | catalogued as rs749133505, COSV100618089; called by muse, mutect2, varscan2
